Surgical pathology report (de-identified scan), TCGA case TCGA-DC-5869, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-5869-01A (Primary Tumor).

[page 1 of 4]
....

Clinical Diagnosis & History:

Female with rectal cancer. No neoadjuvant chemoradiation.

Specimens Submitted:

- 1: SP: Sigmoid and rectum; segmental resection
- 2: SP: Proximal margin; excision
- 3: SP: Distal margin; excision

DIAGNOSIS:

1. SP: Sigmoid and rectum; segmental resection:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Rectum

Tumor Size:

Length is 3.4 cm

Width is 3.4 cm

Maximal thickness is 0.7 cm

Tumor Budding:

Extensive

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Perirectal soft tissue

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

1.6cm from distal resection margin

1.4 cm between deepest tumor portion and deep (radial soft tissue)

** Continued on next page **

[page 2 of 4]
margin

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 1

Total number examined: 19

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC [REDACTED])

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC [REDACTED])

N1 (Metastasis in 1-3 regional lymph nodes)

2. COLON, PROXIMAL MARGIN; EXCISION:

- BENIGN SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.

3. RECTUM, DISTAL MARGIN; EXCISION:

- BENIGN SEGMENT OF RECTUM WITH NO PATHOLOGIC DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1. The specimen is received fresh and is labeled "sigmoid and distal rectum". It consists of a rectosigmoid colon that measures 13.0 cm length and 9 cm in average diameter. The serosal surface is partially peritonealized. The radial resection margin is inked black, the distal margin (without staples) is inked green and the proximal margin (stapled) is inked blue and the specimen is opened to reveal a tumor that is located 8.0 cm from the proximal margin and 1.6 cm from the distal margin. The tumor measures 3.4 cm in length and 3.4 cm in width. Serial sectioning reveals tumor invasion to a depth of 0.7 cm, which is 1.4 cm from the closest radial margin. The remaining mucosa shows no gross abnormalities. Pericolonic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Entire tumor and representative sections from the rest of the specimen are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

** Continued on next page **

[page 3 of 4]
RM - radial margin at closest proximity to tumor
T - tumor
U - uninvolved mucosa
BLN - bisected lymph node
LN - lymph nodes

2.) The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 1.7 x 1.5 x 0.8 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
Undesignated

3.) The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a blue plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.9 x 1.6 x 1.6 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

Summary of Sections:

Part 1: SP: Sigmoid and rectum; segmental resection

Block	Sect.	Site	PCs
1		BLN	1
1		DM	1
4		LN	4
1		PM	1
1		RM	1
5		T	5
1		U	1

Part 2: SP: Proximal margin; excision

Block	Sect.	Site	PCs
1		U	3

Part 3: SP: Distal margin; excision

Block	Sect.	Site	PCs
1		U	4

** Continued on next page **

[page 4 of 4]
** End of Report **

Source: NCI Genomic Data Commons file 217e147a-f601-4121-8982-e5b5870e67bb (TCGA-DC-5869.CB309D0C-A5DB-4054-AF80-89F8B3782A38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).